Somatic mutation profile of tumor specimen TCGA-CH-5744-01A (aliquot TCGA-CH-5744-01A-11D-1576-08) from TCGA case TCGA-CH-5744, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.7 years (23,621 days).
Specimen TCGA-CH-5744-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8078512b-0587-489b-bd26-6ace76767952.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5744-10A (Blood Derived Normal), aliquot TCGA-CH-5744-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f54ba9f-a422-46ad-9682-311d2cf61f2c

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Frame Shift Del 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL13A | c.854C>G p.T285R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV65880168; called by muse, mutect2
- ATP10B | c.4072G>C p.V1358L | Missense Mutation (SNP) | VAF 81/404 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs766095787, COSV59152359; called by muse, mutect2, varscan2
- CATSPERD | c.1561A>C p.K521Q | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV58465420; called by muse, mutect2, varscan2
- CDKL3 | c.1736G>A p.C579Y | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV54741709; called by muse, mutect2, varscan2
- COL6A5 | c.7501G>A p.E2501K (on ENST00000312481; = p.E2497K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs200982668; called by muse, mutect2, varscan2
- CUL3 | c.412A>G p.N138D | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.524); catalogued as COSV52364984; called by muse, mutect2, varscan2
- EBF2 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs199818972, COSV68778709; called by muse, mutect2, varscan2
- ELP1 | c.2044G>A p.V682M | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1245240190, COSV65897846; called by muse, mutect2, varscan2
- EML1 | c.2233G>A p.V745I | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as rs753296372, COSV51745476; called by muse, mutect2, varscan2
- GRIA1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs759117420, COSV53589188; called by muse, mutect2, varscan2
- HYPK | c.364T>G p.*122Gext*11 | Nonstop Mutation (SNP) | VAF 34/133 reads (26%) | catalogued as COSV51039148; called by muse, mutect2, varscan2
- LDLR | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 82/469 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373371572, CM014579; ClinVar: conflicting interpretations of pathogenicity / pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- LRP1B | c.5926T>G p.L1976V | Missense Mutation (SNP) | VAF 102/334 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV67201947, COSV67222004; called by muse, mutect2, varscan2
- NCAM1 | c.1763C>T p.A588V (on ENST00000316851 / NM_181351.5; = p.A578V on NM_000615.7) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57516657; called by muse, mutect2, varscan2
- RYBP | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV72180535; called by muse, mutect2, varscan2
- TRPM6 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62510707; called by muse, mutect2, varscan2
- ZAN | c.1050G>T p.K350N | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as COSV61809358; called by muse, mutect2, varscan2
- MBD6 | c.1500del p.M501Wfs*29 | Frame Shift Del (DEL) | VAF 42/241 reads (17%) | called by mutect2, pindel, varscan2
- CACNA1E | c.4065C>T p.Y1355= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs759912388, COSV62396008; called by muse, mutect2, varscan2
- JAK3 | c.1308A>T p.G436= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV71686067; called by muse, mutect2, varscan2
- KMT2A | c.2097T>C p.A699= | Silent (SNP) | VAF 37/169 reads (22%) | catalogued as COSV63286000; called by muse, mutect2, varscan2
- SPIC | c.252A>G p.Q84= | Silent (SNP) | VAF 147/521 reads (28%) | catalogued as rs554489172, COSV54691196; called by muse, mutect2, varscan2
- TSKS | c.1044G>A p.V348= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1270854134, COSV55875262; called by muse, mutect2, varscan2
- ZSCAN32 | c.695-118A>T | Intron (SNP) | VAF 14/60 reads (23%) | catalogued as rs1407685961, COSV59235285; called by muse, varscan2
